TCGA case TCGA-Q1-A5R2 — Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma (TCGA-CESC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Squamous Cell Neoplasms; Primary site: Cervix uteri; Tissue source site: University of Oklahoma HSC. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/f3cbadb3-3b83-47cd-b8a0-b0e10343a295

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: United States; Age at index: 64 years; Vital status: Alive.

Diagnoses (1)
1. Squamous cell carcinoma, NOS: ICD-O-3 morphology code: 8070/3; ICD-10 code: C53.9; Tissue or organ of origin: Cervix uteri; Site of resection or biopsy: Cervix uteri; Classification of tumor: primary; Age at diagnosis: 64.4 years (23,523 days); Year of diagnosis: 2012; Method of diagnosis: Biopsy; AJCC staging edition: 7th; AJCC pathologic T: TX; AJCC pathologic N: NX; AJCC pathologic M: MX; Tumor grade: G3; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No.
   Pathology details: Consistent pathology review: Yes.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Cisplatin; Days to treatment start: 5 days; Days to treatment end: 48 days; Treatment outcome: Partial Response; Clinical trial indicator: Yes.
   Treatment given: Treatment type: Radiation, External Beam; Days to treatment start: 51 days; Days to treatment end: 198 days; Treatment dose: 600 cGy; Treatment outcome: Partial Response; Number of fractions: 5; Treatment anatomic sites: Primary Tumor Field.
   Treatment given: Treatment type: Brachytherapy, High Dose; Treatment intent type: Adjuvant; Treatment dose: 300 cGy; Chemo concurrent to radiation: Yes; Timepoint category: Postoperative.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Therapeutic agents: Cisplatin; Treatment intent type: Adjuvant; Number of cycles: 6; Chemo concurrent to radiation: Yes; Timepoint category: Postoperative; Treatment frequency: Once Weekly.

Follow-up (3 entries)
- Day 105 (post adjuvant therapy): Disease response: With Tumor; ECOG performance status: 0.
- Day 406 (postoperative): ECOG performance status: 0.
- Days to follow up: 499 days (1.4 years); Disease response: Tumor Free.

Other clinical attributes
- Timepoint category: Initial Diagnosis; Weight: 76 kg; Height: 160 cm; BMI: 29.7.
- Timepoint category: Prior to Diagnosis; Hormonal contraceptive use: Former User.
- Timepoint category: Prior to Diagnosis; Number of pregnancies: 2; Pregnancy outcome: Live Birth.
- Timepoint category: Initial Diagnosis; Menopause status: Postmenopausal; Pregnant at diagnosis: No.

Exposures
- Exposure type: Tobacco; Tobacco smoking status: Lifelong Non-Smoker.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-Q1-A5R2-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT; Initial weight: 30 mg.
  Slide TCGA-Q1-A5R2-01A-01-TS1: Section location: Top; Percent tumor cells: 100; Percent tumor nuclei: 80; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 0; Percent lymphocyte infiltration: 3; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
- Sample TCGA-Q1-A5R2-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-Q1-A5R2-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: Yes; Retrospective collection: No; Menopause status: Post (prior bilateral ovariectomy OR >12 mo since LMP with no prior hysterectomy); History neoadjuvant treatment: No; Tumor status: With tumor; Live birth pregnancy count: 2; Total pregnancy count: 2; Tobacco smoking history indicator: 1; Performance status timing: Post-Adjuvant Therapy; Submitted tumor site: Cervical; Histologic diagnosis: Cervical Squamous Cell Carcinoma; Keratinization squamous cell: Non-keratinizing squamous cell carcinoma; Method initial path diagnosis: Biopsy (cervical / CT-guided / Other); Lymph nodes examined: No; New tumor event diagnosis indicator: No.
- Treatment, Radiation therapy info: Brachytherapy type: HDR.
- Treatment, Concurrent prescription treatment info, Concurrent prescription treatment: Chemo concurrent fractions total: 6.
- Follow-up form: Lost to follow-up: No; Tumor status: Tumor free; Performance status other timing: Post-operative; Treatment outcome at TCGA followup: Complete Response; New tumor event diagnosis indicator: No.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 499 days; disease-specific survival: no event (censored), 499 days; progression-free interval: no event (censored), 499 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-Q1-A5R2-01A-11D-A28A-01): tumor purity 0.57, ploidy 2.96, whole-genome doublings 1.
